Gene-level copy-number profile of tumor specimen MP2PRT-PAREKT-TMP1-A from MP2PRT case MP2PRT-PAREKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,360 days).
Specimen MP2PRT-PAREKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0755eb84-6be9-4f51-90b8-4b84034f548b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAREKT-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/bb5f7aeb-7fa0-4d29-a236-0236b99ee945

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 215; copy number 1: 1,013; copy number 2: 31,108; copy number 3: 7,345; copy number 4: 126; copy number 5: 3,073; copy number 6: 11,502; copy number 7: 975; copy number 9: 1,416; copy number 10: 1,418; copy number 11: 195.

Homozygous deletions (total copy number 0; autosomes only): 215 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,234,174–89,275,787, 6 genes (within-gene range 0–1): IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:182,788,098–182,788,435, 1 gene (within-gene range 0–2): RPL31P15.
- chr3:69,471,452–69,536,693, 2 genes (within-gene range 0–2): RBM43P1, AC099328.1.
- chr3:182,691,928–182,692,285, 1 gene: AC083801.1.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,354,517, 3 genes (within-gene range 0–2): TRGV5P, TRGV5, TRGV4.
- chr7:50,304,068–50,405,101, 2 genes: IKZF1, AC124014.1.
- chr7:142,636,924–142,802,748, 35 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–6): TRDD1, TRDD2.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–7) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–6): IGHVIII-47-1, IGHV3-48.
- chr14:106,566,117–106,579,236, 2 genes (within-gene range 0–2): IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,586,826, 2 genes (within-gene range 0–2): IGHVII-51-2, IGHV3-52.
- chr16:3,065,297–3,157,483, 11 genes (within-gene range 0–3): IL32, RNU1-125P, AC108134.3, RNU1-22P, ZSCAN10, ZNF213-AS1, AC108134.4, ZNF205, ZNF213, CASP16P, AC108134.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16,235 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–49,246,915, 706 genes, copy number 6 (broad region; genes not listed).
- chr4:51,843,000–68,568,527, 221 genes, copy number 6 (within-gene range 5–6) (broad region; genes not listed).
- chr4:68,626,847–69,250,815, 31 genes, copy number 5: AC147055.3, UGT2B15, AC147055.1, AC093720.1, AC021146.8, UGT2B10, AC021146.9, AC021146.4, AC021146.11, AC021146.2, AC021146.3, AC021146.12, AC021146.6, AC021146.1, UGT2A3, AC021146.10, AC021146.5, AC021146.7, UGT2B27P, AC107401.1, UGT2B26P, UGT2B7, AC111000.2, AC111000.5, AC111000.3, AC111000.6, AC111000.1, AC111000.4, UGT2B11, AC114797.1, AC114786.1.
- chr4:69,437,357–190,092,279, 1,589 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–45,696,498, 678 genes, copy number 5 (broad region; genes not listed).
- chr5:50,903,608–181,342,213, 2,216 genes, copy number 5 (broad region; genes not listed).
- chr8:64,091–39,417,378, 808 genes, copy number 6 (broad region; genes not listed).
- chr8:39,522,976–145,066,685, 1,595 genes, copy number 6–7 (broad region; genes not listed).
- chr9:12,134–43,045,120, 754 genes, copy number 6 (broad region; genes not listed).
- chr9:63,127,359–138,253,217, 1,434 genes, copy number 6–7 (broad region; genes not listed).
- chr10:14,061–133,778,699, 2,261 genes, copy number 6–9 (broad region; genes not listed).
- chr14:19,062,316–22,334,685, 228 genes, copy number 5–6 (broad region; genes not listed).
- chr14:22,532,502–105,669,843, 1,743 genes, copy number 6–7 (within-gene range 0–7) (broad region; genes not listed).
- chr14:106,482,435–106,521,073, 7 genes, copy number 6 (within-gene range 0–6): LINC00221, IGHVIV-44-1, IGHVII-44-2, IGHV1-45, IGHV1-46, IGHVII-46-1, IGHV3-47.
- chr14:106,636,672–106,636,786, 1 gene, copy number 6 (within-gene range 2–6): RNA5SP389.
- chr14:106,643,142–106,652,681, 3 genes, copy number 6 (within-gene range 2–6): IGHV3-62, IGHVII-62-1, IGHV3-63.
- chr14:106,675,017–106,879,812, 26 genes, copy number 6 (within-gene range 2–6): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr18:45,034–80,247,514, 1,199 genes, copy number 6 (broad region; genes not listed).
- chr21:9,325,013–9,914,846, 12 genes, copy number 5: CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.
- chr21:12,999,676–46,691,226, 723 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,013. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
